Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4833, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4833-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: GALLBLADDER, CHOLECYSTECTOMY-

CHRONIC ACTIVE CHOLECYSTITIS WITH MARKED INCREASE IN EOSINOPHILS

PART 2: KIDNEY, LEFT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE
- B. FUHRMAN'S NUCLEAR GRADE IS II OF IV
- C. RENAL CELL CARCINOMA GROWS IN ACINAR PATTERN OF GROWTH
- D. THE GREATEST DIAMETER OF THE NEOPLASM IS 5 CM.
- E. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE
- F. NO INVASION OF THE RENAL VEIN IS IDENTIFIED
- G. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM
- I. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE
- J. THE ADRENAL GLAND IS NOT IDENTIFIED
- K. TNM STAGE: pT1b NX MX.
- L. TNM HISTOLOGIC GRADE = G2.

TCGA-B0-4833

Source: NCI Genomic Data Commons file 8ebaf7cb-8fce-49ca-9d56-64979c4e022f (TCGA-B0-4833.6331B3CA-BA2F-4CCD-BBF0-1513489F8A22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).